Gene-level copy-number profile of tumor specimen ALCH-B369-TTP1-A from ALCHEMIST case ALCH-B369, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.5 years (15,531 days).
Specimen ALCH-B369-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a14b1886-4450-4e28-9290-2bb514d4f679.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B369-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/a2c9b593-d0d5-4b5d-8806-904612dc8141

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 2,670; copy number 2: 42,665; copy number 3: 11,628; copy number 4: 1,357; copy number 5: 11; copy number 6: 2; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,253,154–132,257,080, 2 genes (within-gene range 0–2): RNA5-8SP5, MIR663B.
- chr7:1,428,465–1,504,389, 4 genes: MICALL2, AC102953.1, AC102953.2, INTS1.
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr15:25,178,738–25,220,578, 23 genes (within-gene range 0–2): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–1): AC090386.1, AC090386.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,578,478–91,621,421, 3 genes, copy number 5 (within-gene range 3–5): AC233266.1, AC233266.2, AC116050.1.
- chr5:131,155,383–131,224,468, 2 genes, copy number 5: HINT1, LYRM7.
- chr5:172,209,646–172,283,764, 3 genes, copy number 5: UBTD2, AC024561.1, KLF3P1.
- chr9:66,253,424–66,642,277, 3 genes, copy number 5: CDRT15P12, RBPJP2, RAB28P4.
- chr9:66,856,426–66,932,141, 2 genes, copy number 6: ZNF658, BX664608.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 2,669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
